Surgical pathology report (de-identified scan), TCGA case TCGA-CJ-4892, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site MD Anderson Cancer Center, specimen TCGA-CJ-4892-01A (Primary Tumor).

Surgery Date: [REDACTED]

TCGA - CJ - 4892

Pathology Report

DIAGNOSIS

(A) RIGHT KIDNEY:

RENAL CELL CARCINOMA, CONVENTIONAL (CLEAR CELL) TYPE, FUHRMAN NUCLEAR GRADE 2 (5.5 CM), CONFINED TO THE KIDNEY.

Vascular and ureteral margins, no tumor present.

(B) PERICAVAL LYMPH NODES:

Two lymph nodes, no tumor present.

(C) LEFT ADRENAL:

Adrenal myelolipoma (7.5 cm).

GROSS DESCRIPTION

(A) RIGHT KIDNEY - A right kidney (11.0 x 5.5 x 3.5 cm) has a tumor (5.5 x 5.4 x 3.2 cm) which has a yellow, soft cut surface. The tumor is distant from the perirenal adipose tissue margin and approaches into the renal sinus.

No lymph nodes are identified. No other lesions are seen.

Portions are submitted for electron microscopy.

SECTION CODE: A1, renal artery and renal vein and ureteral margins, en face; A2, perirenal adipose tissue margin, en face; A3, A4, tumor with adjacent kidney; A5, A6, tumor with renal sinus tissue; A7, A8, tumor with perirenal fat; A9, A10, distant normal kidney. [REDACTED]
(B) PERICAVAL LYMPH NODES - Multiple yellow-tan irregular fragments of adipose tissue (7.0 x 5.7 x 1.5 cm in aggregate). The specimen is sectioned and two possible lymph nodes are found (0.7 x 0.6 x 0.3 cm and 3.3 x 1.4 x 0.7 cm).

SECTION CODE: B1, one possible lymph node; B2, B3, one possible lymph node serially sectioned [REDACTED]

(C) LEFT ADRENAL - A left adrenal gland (8.5 x 6.5 x 4.5 cm) weighs 140 grams, and has a well-circumscribed mass (7.5 x 6.0 x 4.5 cm) covered by a thin capsule. The cut surface of the mass has pale yellow and dark red hemorrhagic areas. The attached adrenal gland present on one side is unremarkable. A thin, compressed rim of bright gold tissue, resembling adrenal cortex focally surrounds the tumor.

Photograph is obtained.

Portions are submitted for electron microscopy.

INK CODE: Specimen inked in black.

SECTION CODE: C1, vascular margin; C2, C3, adrenal gland with tumor; C4-C8, tumor with perpendicular inked surface; C9, distant normal adrenal gland. [REDACTED]

CLINICAL HISTORY

No history provided.

SNOMED CODES

T-71000, M-82123, T-B3000, M-88700

Source: NCI Genomic Data Commons file 59209786-dcd9-433f-98c7-2e16c0b4281e (TCGA-CJ-4892.0033FCA4-2372-402F-8281-D204B0E7CB5F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).